Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A3KG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A3KG-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Liver, segment 5, partial hepatic resection

Histologic tumor type/subtype: Hepatocellular carcinoma

Histologic grade: Grade 2 of 4 (Edmondson and Steiner)

Tumor location: Segment V

Tumor size: 3.6 cm

ICD-0-3
Carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 lw 12/14/11

Focality/extent: Unifocal

Tumor necrosis/treatment effect: Tumor appears > 95% viable

Vascular invasion: Not identified

Perineural invasion: Not identified

Capsular invasion: Not identified; tumor is 0.1 cm from capsular surface

Margins: Negative for malignancy; tumor is 0.5 cm from the segment IV

margin and 1.3 cm from the segment VI margin

Lymph nodes: None sampled

Background liver: Mild centrilobular cholestasis

AJCC PATHOLOGIC TNM STAGE: pT1 pNX

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Liver, segment 4, partial hepatic resection

- Negative for malignancy

- Liver parenchyma with mild centrilobular cholestasis

C: Gallbladder, cholecystectomy

[page 2 of 3]
- Negative for malignancy
- Gallbladder with no significant pathologic abnormality

Clinical History:

-year-old female with hepatocellular carcinoma.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "segment 5 liver resection" and consists of

a 55 gram (6.8 x 5.3 x 4.2 cm) wedge of liver that has a short stitch at the

segment 6 margin (inked blue) and a long stitch at the segment 4 margin (inked

red) per container. There is a 3.6 x 3.2 x 3.2 cm well-circumscribed but

focally lobulated soft pink/tan mass that is 1.2 cm to the segment 6 margin, 0.5

cm to the segment 4 margin, and grossly bulges the capsule but does not extend

through it. The capsule is smooth and glistening and the remainder of the

parenchyma is red/brown and unremarkable. Tumor and normal tissue are given to

tumor procurement.

Block Summary:

A1-A2 - Perpendicular sections of mass closest to the segment 6 margin

A3-A4 - Perpendicular sections of mass closest to the segment 4 margin

A5 - Mass abutting the capsule

Container B is additionally labeled "segment 4 final margin, stitch final

margin" and consists of a 1.5 gram (2.5 x 2.1 x 0.6 cm) segment of liver that

has a suture on one side indicating final margin, per container. The opposite

side of the suture is partially cauterized. The final margin is inked blue. The

cut surface is unremarkable. Serially sectioned and submitted in B1-B3,

[page 3 of 3]
Container C is additionally labeled "gallbladder" and consists of a 7.5 x 2.7 x 1.4 cm intact gallbladder. The serosa is green/gray, smooth and glistening. The wall is 0.2 cm thick and the lumen is partially filled with a viscous red/brown fluid. The mucosa is red/brown and velvety. Sections of gallbladder and cystic duct margin, en face in C1.

Source: NCI Genomic Data Commons file e0867e07-cde4-448e-a01c-2c9e8021560a (TCGA-BC-A3KG.67A81454-06A8-451D-B855-F9D146CC0348.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).